Somatic mutation profile of tumor specimen MP2PRT-PASWCJ-TMP1-A (aliquot MP2PRT-PASWCJ-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASWCJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.2 years (2,982 days).
Specimen MP2PRT-PASWCJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1dc1d42-c406-4cab-b10a-6231621c2314.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASWCJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASWCJ-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09d17ec3-9468-483a-a500-a96fad20e584

The open-access MAF lists 25 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, Frame Shift Ins 2, Intron 2, Frame Shift Del 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BDNF | c.488C>T p.T163M | Missense Mutation (SNP) | VAF 227/468 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as rs754270781, COSV59237761; called by muse, mutect2, varscan2
- CCDC116 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 183/405 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs762931042, COSV99488925; called by muse, mutect2, varscan2
- DNAH9 | c.9616C>T p.R3206W | Missense Mutation (SNP) | VAF 168/462 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367619575; called by muse, mutect2, varscan2
- GAA | c.1303G>A p.G435S | Missense Mutation (SNP) | VAF 164/396 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs755829900, COSV100162884; called by muse, mutect2, varscan2
- GJA1 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 90/269 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.876); catalogued as rs1169527421, COSV56998863; called by muse, mutect2, varscan2
- LTA4H | c.1000_1003del p.F334Vfs*20 | Frame Shift Del (DEL) | VAF 185/494 reads (37%) | catalogued as rs746470134; called by mutect2, pindel, varscan2
- MUC4 | c.12500C>T p.S4167F | Missense Mutation (SNP) | VAF 256/450 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as rs1167535990; called by muse, mutect2, varscan2
- PRAMEF18 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 113/645 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.102); catalogued as rs1456012727; called by muse, mutect2, varscan2
- CTNNA3 | c.689A>G p.D230G | Missense Mutation (SNP) | VAF 179/395 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ELOA2 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 176/451 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- HDGFL1 | c.452A>G p.D151G | Missense Mutation (SNP) | VAF 294/655 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PM20D1 | c.1194_1195insCCCTGGCCCC p.V399Pfs*8 | Frame Shift Ins (INS) | VAF 133/387 reads (34%) | called by mutect2, pindel, varscan2
- POTEJ | c.2290C>T p.H764Y | Missense Mutation (SNP) | VAF 332/732 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- RUNX1 | c.38_39del p.Y13Sfs*16 | Frame Shift Del (DEL) | VAF 152/333 reads (46%) | called by mutect2, pindel*, varscan2*
- SOGA3 | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 191/553 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TRAM1L1 | c.1088A>T p.K363M | Missense Mutation (SNP) | VAF 148/370 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- UBA2 | c.268_269insGGCCG p.V90Gfs*10 | Frame Shift Ins (INS) | VAF 61/229 reads (27%) | called by mutect2, pindel, varscan2
- ANK2 | c.9474G>A p.P3158= | Silent (SNP) | VAF 136/284 reads (48%) | catalogued as rs145111737, COSV52177219; ClinVar: likely benign; called by muse, varscan2
- CRH | c.147G>A p.P49= | Silent (SNP) | VAF 38/920 reads (4%) | catalogued as rs759361191; called by muse, mutect2
- DBX2 | c.435G>A p.P145= | Silent (SNP) | VAF 186/418 reads (44%) | catalogued as rs933265525, COSV60336068; called by muse, mutect2, varscan2
- IGFL1 | c.150C>A p.P50= | Silent (SNP) | VAF 203/445 reads (46%) | called by muse, mutect2, varscan2
- PTPN14 | c.2763G>A p.A921= | Silent (SNP) | VAF 32/536 reads (6%) | catalogued as rs146527644, COSV65283594; called by muse, mutect2
- CDH8 | c.*717A>C | 3'UTR (SNP) | VAF 158/378 reads (42%) | called by muse, mutect2, varscan2
- HOPX | c.145-1932G>A | Intron (SNP) | VAF 26/446 reads (6%) | catalogued as rs141906115, COSV100497084; called by muse, mutect2
- PNKD | c.236+1201G>A | Intron (SNP) | VAF 128/298 reads (43%) | called by muse, mutect2, varscan2
